Somatic mutation profile of tumor specimen TCGA-ZG-A8QZ-01A (aliquot TCGA-ZG-A8QZ-01A-11D-A377-08) from TCGA case TCGA-ZG-A8QZ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.7 years (23,980 days).
Specimen TCGA-ZG-A8QZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b581f198-f522-4c1d-86a5-e52e2e1b0809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A8QZ-10A (Blood Derived Normal), aliquot TCGA-ZG-A8QZ-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a53030f6-d851-4d8e-8a4f-d94a372210c6

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC6 | c.10722T>A p.H3574Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101427998; called by muse, mutect2, varscan2
- CFHR3 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.026); catalogued as rs1255177528, COSV100807467; called by muse, mutect2, varscan2
- FAT2 | c.8155C>G p.Q2719E | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV55814140, COSV99942058; called by muse, mutect2, varscan2
- GSTO1 | c.59C>G p.P20R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs769727460, COSV100866915; called by mutect2, varscan2
- HDAC3 | c.474C>G p.L158= | Splice Region (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100539476; called by muse, mutect2, varscan2
- MYLK4 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV51147658, COSV99193729; called by muse, mutect2, varscan2
- NAT16 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV55865043; called by muse, mutect2, varscan2
- NLRP4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs370421219; called by muse, mutect2, varscan2
- PAPOLB | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1348540865, COSV68201426; called by muse, mutect2
- PCDHB7 | c.1218G>C p.E406D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.084); catalogued as COSV50790091, COSV99176370; called by muse, mutect2, varscan2
- PCNX1 | c.4985T>C p.L1662P | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99454776; called by muse, mutect2, varscan2
- PDYN | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377075531, COSV54100958; called by muse, mutect2, varscan2
- PTPRB | c.5144G>A p.R1715Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs371535586; called by muse, mutect2, varscan2
- ROBO2 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV59895891; called by muse, mutect2, varscan2
- SIAH3 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs1474556237, COSV68551398; called by muse, mutect2, varscan2
- SUN2 | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99325440; called by muse, mutect2, varscan2
- TTLL2 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs200167585, COSV53442986; called by muse, mutect2, varscan2
- ZNF628 | c.2368G>T p.A790S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs778836601, COSV99219864; called by muse, mutect2, varscan2
- WDR48 | c.69del p.D23Efs*20 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- FAM209A | c.69T>G p.S23= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV99711253; called by muse, mutect2, varscan2
- FREM2 | c.7833T>G p.P2611= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV99747563; called by muse, mutect2, varscan2
- OR5K3 | c.390G>A p.L130= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs1454906296, COSV101051619; called by muse, mutect2, varscan2
- RFWD3 | c.1332A>G p.V444= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1240375818, COSV100736189; called by muse, mutect2, varscan2
- WASF4P | n.1388T>C | RNA (SNP) | VAF 13/27 reads (48%) | catalogued as rs1401397874; called by muse, mutect2, varscan2
